Somatic mutation profile of tumor specimen TCGA-FR-A69P-06A (aliquot TCGA-FR-A69P-06A-21D-A30X-08) from TCGA case TCGA-FR-A69P, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 34.7 years (12,679 days).
Specimen TCGA-FR-A69P-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1aed097a-c642-428a-b917-902bc1bfc8c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FR-A69P-10A (Blood Derived Normal), aliquot TCGA-FR-A69P-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8bc53e15-434f-42ab-94ec-5588de4a9cc8

The open-access MAF lists 260 somatic variants for this specimen: 174 protein-altering or splice-affecting, 79 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 163, Silent 79, Nonsense Mutation 9, Splice Region 2, Intron 2, RNA 2, 3'Flank 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NLRP3 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs180177458, CM055132, COSV60230233; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 216/298 reads (72%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OCA2 | c.1922C>T p.S641L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs868238523, COSV62337400, COSV62339851, COSV62344458; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PCSK5 | c.2772G>A p.W924* | Nonsense Mutation (SNP) | VAF 27/35 reads (77%) | hotspot (GDC flag); catalogued as rs1170804599, COSV70449546; called by muse, mutect2, varscan2
- PROS1 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs199469500, CM961188, COSV67776876; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs768578610, COSV51702735, COSV51707828; called by muse, mutect2, varscan2
- ABCC4 | c.1164C>T p.T388= | Splice Region (SNP) | VAF 25/30 reads (83%) | catalogued as COSV65317607; called by muse, mutect2, varscan2
- ACSL1 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763342330, COSV55666071; called by muse, mutect2, varscan2
- ADAM11 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV52349480; called by muse, mutect2, varscan2
- ADAMTS18 | c.2581C>T p.P861S | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.461); catalogued as rs866658923, COSV51401674; called by muse, mutect2, varscan2
- ADAMTS6 | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV66863920; called by muse, mutect2, varscan2
- ADCK1 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 123/253 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs776632140, COSV53082116; called by muse, mutect2, varscan2
- ADCY10 | c.4073T>G p.V1358G | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV63244283; called by muse, mutect2, varscan2
- ADCYAP1 | c.5C>T p.T2I | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV52487365; called by muse, mutect2, varscan2
- ADGRA3 | c.2608C>T p.P870S | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV51567549; called by muse, mutect2, varscan2
- ADH1A | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52926019; called by muse, mutect2, varscan2
- ADRA1D | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65241850; called by muse, mutect2, varscan2
- AMY1C | c.879G>A p.K293= | Splice Region (SNP) | VAF 69/504 reads (14%) | catalogued as COSV64407220; called by muse, mutect2, varscan2
- ANKFN1 | c.1673C>T p.S558L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV59458084; called by muse, mutect2, varscan2
- ANKRD30A | c.3385G>A p.E1129K (on ENST00000611781; = p.E1073K on NM_052997.2) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV64607971; called by muse, mutect2, varscan2
- ARFGEF1 | c.641T>C p.L214S | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as COSV51615917; called by muse, mutect2, varscan2
- ARID1A | c.5239C>T p.P1747S | Missense Mutation (SNP) | VAF 56/75 reads (75%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.777); catalogued as COSV61387481; called by muse, mutect2, varscan2
- ASXL3 | c.4108C>T p.P1370S | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs1349869581, COSV52458378; called by muse, mutect2, varscan2
- BAZ2B | c.3477A>C p.K1159N | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs776214814, COSV54276612; called by muse, mutect2, varscan2
- BBS9 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54157835; called by muse, mutect2, varscan2
- BCL6 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51655322; called by muse, mutect2, varscan2
- BRINP3 | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs1172739869, COSV66535014; called by muse, mutect2, varscan2
- BSN | c.9842C>T p.P3281L | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV56526123; called by muse, mutect2, varscan2
- C22orf23 | c.628C>T p.L210F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV50778594; called by muse, mutect2, varscan2
- CACNA1C | c.3955G>A p.E1319K | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV59696736; called by muse, mutect2, varscan2
- CAMK1G | c.706T>C p.Y236H | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50525572; called by muse, mutect2, varscan2
- CDR2 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.185); catalogued as rs1384763549, COSV51677358; called by muse, mutect2, varscan2
- CEACAM7 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 85/127 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV50074479; called by muse, mutect2, varscan2
- CHD7 | c.4879C>T p.H1627Y | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs769675553, COSV101418500; called by muse, mutect2, varscan2
- COL1A2 | c.3037G>A p.E1013K | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as rs1435469001, COSV51958327; called by muse, mutect2, varscan2
- COL27A1 | c.4645C>T p.P1549S | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV61930196; called by muse, mutect2, varscan2
- COL4A4 | c.2809G>A p.E937K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.272); catalogued as COSV61635916; called by muse, varscan2
- CPNE2 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV51964641; called by muse, mutect2, varscan2
- CSMD3 | c.4616G>A p.R1539Q (on ENST00000297405 / NM_001363185.1; = p.R1435Q on NM_052900.3) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1472368863, COSV52210021; called by muse, mutect2, varscan2
- CUX1 | c.3044T>C p.L1015P | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99473341; called by muse, mutect2, varscan2
- CYP2B6 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as COSV57845257; called by muse, mutect2, varscan2
- DAW1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV59363580; called by muse, mutect2, varscan2
- DBH | c.683C>T p.T228I | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55042203; called by muse, mutect2, varscan2
- DLEC1 | c.3293T>G p.L1098R | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57305557; called by muse, mutect2, varscan2
- DMD | c.10172G>A p.R3391Q | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1423537877, COSV58896676; called by muse, mutect2, varscan2
- DSP | c.3464G>T p.W1155L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.84); PolyPhen benign (0.078); catalogued as COSV65795317; called by muse, mutect2, varscan2
- ELK4 | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.111); catalogued as COSV56986106; called by muse, mutect2, varscan2
- ELOA2 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as rs769385321, COSV55294609; called by muse, mutect2, varscan2
- EPHA6 | c.2653G>A p.D885N (on ENST00000389672 / NM_001080448.3; = p.D277N on NM_173655.4) | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV67558974; called by muse, mutect2, varscan2
- ERCC6L | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as rs759122393, COSV100559291; called by muse, mutect2, varscan2
- ERCC6L | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV100559292; called by muse, mutect2, varscan2
- FANCM | c.1748G>A p.G583D | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57505821; called by muse, varscan2
- FASTKD3 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 54/67 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs1414015760, COSV52946435; called by muse, mutect2, varscan2
- FAT3 | c.13062G>A p.W4354* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV53164681; called by muse, mutect2, varscan2
- FCRL3 | c.656G>T p.R219M | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs575879706, COSV63840625, COSV63844510; called by muse, mutect2, varscan2
- FGD6 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 67/81 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV59692726, COSV59694451, COSV59696614; called by muse, mutect2, varscan2
- FLG | c.8530G>A p.E2844K | Missense Mutation (SNP) | VAF 328/1360 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs567565013, COSV64247650; called by muse, mutect2, varscan2
- FLG | c.6130G>A p.A2044T | Missense Mutation (SNP) | VAF 408/778 reads (52%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.706); catalogued as COSV64247654; called by muse, mutect2, varscan2
- FMN2 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV60450190; called by muse, mutect2, varscan2
- GAPDHS | c.473G>A p.W158* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as rs1014907524, COSV55881293; called by muse, mutect2, varscan2
- GDF3 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 34/37 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs968641196, COSV61713479; called by muse, mutect2, varscan2
- GPR137B | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 106/225 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777123792, COSV63991523; called by muse, mutect2, varscan2
- GRIA2 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.745); catalogued as COSV52403514; called by muse, mutect2, varscan2
- GRK5 | c.1201G>A p.V401I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.979); catalogued as COSV100963296; called by muse, mutect2, varscan2
- GRM3 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV64466563; called by muse, mutect2, varscan2
- GTF2F1 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs1209004307, COSV101081443; called by muse, mutect2, varscan2
- HESX1 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs781729398, COSV55843212; called by muse, mutect2, varscan2
- HNF4G | c.62G>A p.G21E (on ENST00000354370 / NM_001330561.2; = p.G68E on NM_004133.5) | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62972887; called by muse, mutect2, varscan2
- IGHV6-1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.911); catalogued as rs543799892; called by muse, mutect2, varscan2
- IGSF1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 52/76 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1227057524, COSV63839847; called by muse, mutect2, varscan2
- IST1 | c.943C>T p.P315S (on ENST00000535424 / NM_001270976.1; = p.V300= on NM_014761.4) | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as rs775807288, COSV58665959, COSV58666227; called by muse, mutect2, varscan2
- ITGAX | c.3385A>G p.K1129E | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51650720; called by muse, mutect2, varscan2
- KCNG1 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV65370338; called by muse, mutect2, varscan2
- KIAA0232 | c.1981C>T p.P661S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.187); catalogued as COSV56928769; called by muse, mutect2, varscan2
- KIAA1217 | c.5387C>T p.S1796F | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV56815552; called by muse, mutect2, varscan2
- KIF26A | c.2311C>T p.P771S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV59470065; called by muse, mutect2, varscan2
- KL | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV66308235; called by muse, mutect2, varscan2
- KPNB1 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV51600209; called by muse, mutect2, varscan2
- LILRB4 | c.1060G>A p.E354K (on ENST00000391733 / NM_001278428.3; = p.E353K on NM_001278426.3) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as COSV54408231; called by muse, varscan2
- LRBA | c.7269G>A p.W2423* | Nonsense Mutation (SNP) | VAF 23/44 reads (52%) | catalogued as COSV63963304; called by muse, mutect2, varscan2
- LRP12 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52630954, COSV52633872; called by muse, mutect2, varscan2
- MGAT3 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.451); catalogued as rs1207257006, COSV57864814; called by muse, mutect2, varscan2
- MIIP | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as rs1013859842, COSV52428615; called by muse, mutect2, varscan2
- MTTP | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.57); catalogued as COSV55509242; called by muse, mutect2, varscan2
- MUC16 | c.38851A>T p.T12951S | Missense Mutation (SNP) | VAF 121/176 reads (69%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.992); catalogued as COSV67489033; called by muse, mutect2, varscan2
- MUC16 | c.30641G>A p.W10214* | Nonsense Mutation (SNP) | VAF 25/50 reads (50%) | catalogued as COSV67489041; called by muse, mutect2, varscan2
- MUC16 | c.20876C>T p.S6959F | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.414); catalogued as COSV67454402; called by muse, mutect2, varscan2
- MUC4 | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.955); catalogued as COSV62188985; called by muse, mutect2, varscan2
- MUS81 | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV57261384; called by muse, mutect2, varscan2
- MYH7 | c.2756T>G p.V919G | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV62523110; called by muse, mutect2, varscan2
- MYO5C | c.2854G>A p.D952N | Missense Mutation (SNP) | VAF 186/314 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs767982964, COSV55911354; called by muse, mutect2, varscan2
- MYO7B | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371035844; called by muse, mutect2, varscan2
- NKAIN3 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs371183258; called by muse, mutect2, varscan2
- NLRP11 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs762382161, COSV64086171; called by muse, mutect2, varscan2
- NLRP8 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as rs532289570, COSV52587105; called by muse, mutect2, varscan2
- NOSTRIN | c.237G>A p.M79I (on ENST00000317647 / NM_001039724.4; = p.M1? on NM_052946.3) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58323133; called by muse, mutect2, varscan2
- NPSR1 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 65/98 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV62206681; called by muse, mutect2, varscan2
- NRXN1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as COSV68026326; called by muse, mutect2, varscan2
- NTRK3 | c.2302A>G p.K768E (on ENST00000360948 / NM_001012338.2; = p.K754E on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV62313866; called by muse, mutect2, varscan2
- NUDT12 | c.1112T>G p.V371G | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1192484877, COSV50092520; called by muse, mutect2, varscan2
- NUP85 | c.1072C>T p.H358Y | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as COSV55466451; called by muse, varscan2
- OAZ3 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 106/193 reads (55%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV58619353; called by muse, mutect2, varscan2
- OPRK1 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.167); catalogued as COSV55571867, COSV55573448; called by muse, mutect2, varscan2
- OR13C2 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73377660; called by muse, mutect2, varscan2
- OR2H2 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.369); catalogued as COSV63544283; called by muse, mutect2, varscan2
- OR52L1 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs867894367, COSV59985811; called by muse, mutect2, varscan2
- OR6T1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as COSV58306859, COSV58308509; called by muse, mutect2, varscan2
- OSBPL6 | c.2506A>G p.N836D | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51928636; called by muse, mutect2, varscan2
- P2RY1 | c.269T>C p.M90T | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59310307; called by muse, mutect2, varscan2
- PALD1 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0.055); catalogued as rs747709218, COSV54971569; called by muse, mutect2, varscan2
- PAWR | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60924752; called by muse, mutect2
- PCLO | c.11686C>T p.P3896S | Missense Mutation (SNP) | VAF 96/450 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV61616189; called by muse, mutect2, varscan2
- PCLO | c.9840G>A p.M3280I | Missense Mutation (SNP) | VAF 102/157 reads (65%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV61638945, COSV61643905, COSV61661151; called by muse, mutect2, varscan2
- PCLO | c.7667C>T p.S2556F | Missense Mutation (SNP) | VAF 61/99 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61652658; called by muse, mutect2, varscan2
- PDE1C | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.7); catalogued as rs866066614, COSV68810509; called by muse, mutect2, varscan2
- PID1 | c.445G>A p.D149N (on ENST00000354069 / NM_001330156.1; = p.D147N on NM_017933.5) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs777064626, COSV62474437, COSV62478680; called by muse, mutect2, varscan2
- PNLIPRP3 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV65049494; called by muse, mutect2
- PPIL2 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1279034844, COSV58605497; called by muse, mutect2, varscan2
- PPM1K | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.053); catalogued as COSV55797639; called by muse, mutect2, varscan2
- PPP1R3A | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.03); catalogued as COSV52891612; called by muse, mutect2, varscan2
- PRAMEF15 | c.1345C>T p.H449Y | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as rs1308445544; called by mutect2, varscan2
- PREPL | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs79152801, COSV99576540; called by mutect2, varscan2
- PRPF38B | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV64224499; called by muse, mutect2, varscan2
- PRRC2B | c.3229C>T p.R1077C | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs776283820, COSV61934390; called by muse, mutect2, varscan2
- PXDNL | c.2773C>T p.P925S | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1390297647, COSV62487318; called by muse, mutect2, varscan2
- QSOX1 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.393); catalogued as rs770038519, COSV62581497; called by muse, mutect2, varscan2
- RAG2 | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs139419162, COSV57556829; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.911); catalogued as COSV52864778; called by muse, mutect2, varscan2
- RGS16 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 65/172 reads (38%) | catalogued as COSV62375628, COSV62375949; called by muse, mutect2, varscan2
- RNF216 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1314779582, COSV66292442; called by muse, mutect2, varscan2
- RYR2 | c.3344T>C p.V1115A | Missense Mutation (SNP) | VAF 144/354 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as rs1420517050, COSV63709686; called by muse, mutect2, varscan2
- SAMD14 | c.1210C>T p.R404W (on ENST00000330175 / NM_001257359.2; = p.R432W on NM_174920.4) | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs758614118, COSV50304731; called by muse, mutect2, varscan2
- SCN10A | c.5311C>T p.L1771F | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71861176; called by muse, mutect2, varscan2
- SDK2 | c.2107A>G p.T703A | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV66195169; called by muse, mutect2, varscan2
- SDR16C5 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58128014, COSV58128109; called by muse, mutect2, varscan2
- SELP | c.1916G>A p.G639E | Missense Mutation (SNP) | VAF 128/234 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs575279804, COSV55253396; called by muse, mutect2, varscan2
- SEMA4C | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs774867981, COSV59691614; called by muse, mutect2, varscan2
- SF3A2 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 58/93 reads (62%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.059); catalogued as COSV55556686; called by muse, mutect2, varscan2
- SH3GL3 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs772850819, COSV61060935; called by muse, mutect2, varscan2
- SLAIN2 | c.1082C>T p.S361L | Missense Mutation (SNP) | VAF 46/77 reads (60%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV51910035; called by muse, mutect2, varscan2
- SLAMF8 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV56989694; called by muse, mutect2, varscan2
- SLC46A3 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 71/102 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57183786; called by muse, mutect2, varscan2
- SLC5A11 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV61742336, COSV61743408; called by muse, mutect2, varscan2
- SLC5A12 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs145373937, COSV54820770; called by muse, mutect2, varscan2
- SLC9C2 | c.1376C>A p.T459K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV62948819; called by muse, mutect2, varscan2
- SLFN12 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as COSV59225794, COSV59227435; called by muse, mutect2, varscan2
- SLITRK1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV65676579; called by muse, mutect2, varscan2
- SLITRK6 | c.1796G>A p.R599Q | Missense Mutation (SNP) | VAF 82/163 reads (50%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs267603864, COSV68390277; called by muse, mutect2, varscan2
- SPPL2B | c.629G>C p.G210A | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV66317360; called by muse, mutect2, varscan2
- ST6GAL2 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 39/62 reads (63%) | PolyPhen benign (0.135); catalogued as COSV64529701; called by muse, mutect2, varscan2
- STAB1 | c.4187G>A p.G1396E | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868016633, COSV58742073; called by muse, mutect2, varscan2
- STOX2 | c.1624C>T p.Q542* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV57855794; called by muse, mutect2, varscan2
- TBC1D19 | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs201835858, COSV53520900; called by muse, mutect2, varscan2
- TBPL2 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV55973587; called by muse, mutect2, varscan2
- TBX15 | c.598C>T p.P200S (on ENST00000369429 / NM_001330677.2; = p.P94S on NM_152380.3) | Missense Mutation (SNP) | VAF 138/279 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52875386; called by muse, mutect2, varscan2
- TCP11 | c.612G>A p.M204I (on ENST00000512012; = p.M142I on NM_018679.5) | Missense Mutation (SNP) | VAF 66/88 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV55135705; called by muse, mutect2, varscan2
- TENM4 | c.5033A>G p.N1678S | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV53663839; called by muse, mutect2
- THSD4 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs368068532; called by muse, mutect2, varscan2
- TLE6 | c.1040G>A p.R347K (on ENST00000246112 / NM_001143986.2; = p.R224K on NM_024760.3) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.496); catalogued as COSV55737481; called by muse, mutect2, varscan2
- TLR5 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV60560572; called by muse, mutect2, varscan2
- TNFSF18 | c.272G>A p.W91* | Nonsense Mutation (SNP) | VAF 51/173 reads (29%) | catalogued as COSV53440874; called by muse, mutect2, varscan2
- TRPC5 | c.2896G>A p.E966K | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV53301546; called by muse, mutect2, varscan2
- TTBK2 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as COSV99142564; called by muse, mutect2, varscan2
- TTC39B | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.519); catalogued as COSV52609749; called by muse, mutect2, varscan2
- TTC9 | c.490T>G p.F164V | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.999); catalogued as COSV56448056, COSV56449027; called by muse, mutect2, varscan2
- VCAN | c.2761G>A p.E921K | Missense Mutation (SNP) | VAF 50/67 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54115035; called by muse, mutect2, varscan2
- ZC2HC1A | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.756); catalogued as COSV55670259, COSV55671149; called by muse, mutect2, varscan2
- ZNF44 | c.674C>T p.T225I (on ENST00000356109 / NM_001164276.2; = p.T177I on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV61136183; called by muse, mutect2, varscan2
- ZNF592 | c.2827C>T p.P943S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV55439199; called by muse, mutect2, varscan2
- ZNF641 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT tolerated (0.33); PolyPhen benign (0.133); catalogued as COSV56389728; called by muse, mutect2, varscan2
- ZNF98 | c.1541G>A p.G514E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); catalogued as COSV63337298; called by muse, mutect2, varscan2
- ZNRF3 | c.2266C>T p.Q756* (on ENST00000544604 / NM_001206998.2; = p.Q656* on NM_032173.3) | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as COSV60437898; called by muse, mutect2, varscan2
- ANK3 | c.12704A>C p.D4235A (on ENST00000280772 / NM_001320874.2; = p.D859A on NM_001149.3) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); called by muse, mutect2
- RBP3 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- AADACL2 | c.117C>T p.I39= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs146278742; called by muse, mutect2, varscan2
- ABLIM1 | c.1470C>T p.S490= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs1278093601, COSV53314742; called by muse, mutect2, varscan2
- ACSM5 | c.264C>T p.I88= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV59370864; called by muse, mutect2, varscan2
- ACTL9 | c.1137C>T p.S379= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs548848075, COSV100185545, COSV61006062; called by muse, mutect2, varscan2
- ADAM15 | c.117C>T p.A39= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV55062705; called by muse, mutect2
- AHR | c.2190C>T p.P730= | Silent (SNP) | VAF 54/76 reads (71%) | catalogued as rs752627879, COSV54125949; called by muse, mutect2, varscan2
- AIPL1 | c.798C>T p.A266= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV51508652; called by muse, mutect2, varscan2
- ALDH1A2 | c.333C>T p.D111= | Silent (SNP) | VAF 66/314 reads (21%) | catalogued as COSV51089443; called by muse, mutect2, varscan2
- AOAH | c.1095C>T p.I365= | Silent (SNP) | VAF 67/110 reads (61%) | catalogued as rs748997190, COSV51743688; called by muse, mutect2, varscan2
- ATP12A | c.2319C>T p.I773= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as rs755436718, COSV54520790; called by muse, mutect2, varscan2
- ATP2B4 | c.3378C>T p.S1126= | Silent (SNP) | VAF 64/120 reads (53%) | catalogued as COSV58183049; called by muse, mutect2, varscan2
- B3GAT2 | c.615C>T p.S205= | Silent (SNP) | VAF 34/42 reads (81%) | catalogued as rs759031870, COSV57774191; called by muse, mutect2, varscan2
- CACNA1G | c.2361C>T p.A787= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs753748477, COSV61736998; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC9B | c.837G>A p.L279= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV66876155; called by muse, mutect2, varscan2
- CEACAM8 | c.990C>T p.L330= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99747896; called by muse, mutect2, varscan2
- CILP | c.1887C>T p.P629= | Silent (SNP) | VAF 37/159 reads (23%) | catalogued as COSV56027457; called by muse, mutect2, varscan2
- CNGB1 | c.3612C>T p.S1204= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV51906195; called by muse, mutect2, varscan2
- CNTNAP1 | c.1113C>T p.F371= | Silent (SNP) | VAF 63/101 reads (62%) | catalogued as rs1254716843, COSV52847801; called by muse, mutect2, varscan2
- CSMD3 | c.10704G>A p.K3568= (on ENST00000297405 / NM_001363185.1; = p.K3399= on NM_052900.3) | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV52296881; called by muse, mutect2, varscan2
- CUX1 | c.3043C>T p.L1015= | Silent (SNP) | VAF 36/131 reads (27%) | catalogued as COSV99473338; called by muse, mutect2, varscan2
- DNAH7 | c.11562C>T p.F3854= | Silent (SNP) | VAF 32/51 reads (63%) | catalogued as COSV56761188; called by muse, mutect2, varscan2
- DNAJB1 | c.363G>A p.G121= | Silent (SNP) | VAF 37/63 reads (59%) | catalogued as COSV54317895; called by muse, mutect2, varscan2
- FOXS1 | c.870C>T p.P290= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV54068011, COSV99639646; called by muse, mutect2, varscan2
- GABRB1 | c.1155G>A p.T385= | Silent (SNP) | VAF 38/66 reads (58%) | catalogued as COSV54976701; called by muse, mutect2, varscan2
- GRK5 | c.1200G>A p.R400= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs1359909012, COSV100963294; called by muse, mutect2, varscan2
- GTF2F1 | c.450C>T p.A150= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV101081446; called by muse, mutect2, varscan2
- IGHV3-20 | c.102G>A p.G34= | Silent (SNP) | VAF 44/124 reads (35%) | called by muse, mutect2
- IGKV3-7 | c.276C>T p.F92= | Silent (SNP) | VAF 38/84 reads (45%) | called by muse, mutect2, varscan2
- IQGAP1 | c.1839C>T p.S613= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV51590567; called by muse, mutect2, varscan2
- IRAK2 | c.876T>C p.G292= | Silent (SNP) | VAF 38/71 reads (54%) | catalogued as COSV56535176; called by muse, mutect2, varscan2
- ITGAM | c.2169C>T p.I723= (on ENST00000648685 / NM_001145808.2; = p.I722= on NM_000632.4) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs375935866; called by muse, mutect2, varscan2
- KAT6B | c.5380T>C p.L1794= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV54753543; called by muse, mutect2, varscan2
- KCMF1 | c.990T>G p.R330= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV69054668; called by muse, mutect2, varscan2
- KCNH5 | c.441G>A p.T147= | Silent (SNP) | VAF 41/82 reads (50%) | catalogued as rs753750382, COSV59752889; called by muse, mutect2, varscan2
- KIF5A | c.1077G>A p.T359= | Silent (SNP) | VAF 46/49 reads (94%) | catalogued as rs552427920, COSV54058468, COSV99673334; called by muse, mutect2, varscan2
- KIR3DL2 | c.1065C>T p.L355= | Silent (SNP) | VAF 22/31 reads (71%) | catalogued as COSV54395023; called by muse, mutect2, varscan2
- KRT15 | c.1332G>A p.V444= | Silent (SNP) | VAF 59/119 reads (50%) | catalogued as rs150390543; called by muse, mutect2, varscan2
- L1TD1 | c.318C>T p.I106= | Silent (SNP) | VAF 39/53 reads (74%) | catalogued as COSV63134211; called by muse, mutect2, varscan2
- LAMA3 | c.5797C>T p.L1933= (on ENST00000313654 / NM_198129.4; = p.L324= on NM_000227.6) | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV52542099; called by muse, mutect2, varscan2
- LCE3E | c.33A>G p.Q11= | Silent (SNP) | VAF 78/127 reads (61%) | catalogued as rs777621256, COSV64231683; called by muse, mutect2, varscan2
- LGALS4 | c.585C>T p.F195= | Silent (SNP) | VAF 41/77 reads (53%) | catalogued as rs774760271, COSV57044935; called by muse, mutect2, varscan2
- LRP5 | c.3546G>A p.K1182= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as COSV53722671; called by muse, mutect2, varscan2
- MAOB | c.696G>A p.E232= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as rs1209162951, COSV65204738, COSV65206662; called by muse, mutect2, varscan2
- MICAL3 | c.2898C>T p.A966= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs368533602; called by muse, mutect2
- MTNR1A | c.705G>A p.R235= | Silent (SNP) | VAF 63/124 reads (51%) | catalogued as COSV56155639, COSV56156629; called by muse, mutect2, varscan2
- MTUS1 | c.3057G>A p.R1019= (on ENST00000262102 / NM_001363061.1; = p.R185= on NM_020749.4) | Silent (SNP) | VAF 34/61 reads (56%) | catalogued as COSV50581628; called by muse, mutect2, varscan2
- MUC16 | c.29814G>A p.V9938= | Silent (SNP) | VAF 140/220 reads (64%) | catalogued as rs1403759737, COSV67459794; called by muse, mutect2, varscan2
- MXRA5 | c.4203G>A p.G1401= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV54248047, COSV99475827; called by muse, mutect2, varscan2
- NOTCH2 | c.4911C>T p.D1637= | Silent (SNP) | VAF 160/281 reads (57%) | catalogued as COSV56703630; called by muse, mutect2, varscan2
- ONECUT1 | c.624C>T p.P208= | Silent (SNP) | VAF 29/173 reads (17%) | catalogued as COSV59948497, COSV59950792; called by muse, mutect2, varscan2
- OPLAH | c.987C>T p.F329= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as rs781839720, COSV70677303; called by muse, mutect2, varscan2
- OR10G8 | c.147G>A p.V49= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as rs992766885, COSV70909323; called by muse, mutect2, varscan2
- OR4C15 | c.99C>T p.F33= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs760696526, COSV58951213, COSV58956039; called by muse, mutect2, varscan2
- OR52M1 | c.754C>T p.L252= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs372025195; called by muse, mutect2, varscan2
- PCLO | c.8958G>A p.G2986= | Silent (SNP) | VAF 177/275 reads (64%) | catalogued as rs932203846, COSV61661162; called by muse, mutect2, varscan2
- PKD1L1 | c.8058C>T p.F2686= | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as COSV51844671; called by muse, mutect2, varscan2
- PLOD3 | c.1602C>T p.F534= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as rs768164152, COSV56185532; called by muse, mutect2, varscan2
- POTEF | c.3162G>A p.Q1054= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100665412; called by mutect2, varscan2
- PRICKLE2 | c.672C>T p.L224= (on ENST00000295902; = p.L168= on NM_198859.4) | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs1362874246, COSV55770984; called by muse, mutect2, varscan2
- PRR19 | c.357G>A p.R119= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as rs1291167961; called by muse, mutect2
- RHCG | c.594C>T p.I198= | Silent (SNP) | VAF 31/156 reads (20%) | catalogued as COSV51518208; called by muse, mutect2, varscan2
- RPTN | c.2103G>A p.L701= | Silent (SNP) | VAF 107/309 reads (35%) | catalogued as COSV60168950; called by muse, mutect2
- SERPINA1 | c.996C>T p.I332= | Silent (SNP) | VAF 63/195 reads (32%) | catalogued as COSV63346294; called by muse, mutect2, varscan2
- SGSM1 | c.1740C>T p.D580= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV68513013; called by muse, mutect2, varscan2
- SLC41A3 | c.168G>A p.E56= | Silent (SNP) | VAF 78/173 reads (45%) | catalogued as COSV59990164; called by muse, mutect2, varscan2
- SMPD3 | c.189C>T p.F63= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs761103474, COSV54715432; called by muse, mutect2, varscan2
- SPTBN2 | c.1116C>T p.I372= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV59460228; called by muse, mutect2, varscan2
- SVOPL | c.501G>A p.T167= (on ENST00000419765; = p.T15= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/122 reads (17%) | catalogued as rs371993600; called by muse, mutect2, varscan2
- SYN2 | c.822C>T p.H274= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs770803088, COSV55139923; called by muse, mutect2, varscan2
- TECPR1 | c.3486C>T p.P1162= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs758608235, COSV58363235; called by muse, mutect2, varscan2
- TMEM176A | c.585C>T p.L195= | Silent (SNP) | VAF 57/99 reads (58%) | catalogued as rs558833810, COSV50244549; called by muse, mutect2, varscan2
- TRAPPC9 | c.1569C>T p.L523= | Silent (SNP) | VAF 27/47 reads (57%) | catalogued as COSV66905100; called by muse, mutect2, varscan2
- TTBK1 | c.2193G>A p.G731= | Silent (SNP) | VAF 15/20 reads (75%) | catalogued as rs1339721404, COSV52495813; called by muse, mutect2
- TTN | c.50886G>A p.P16962= (on ENST00000591111; = p.P9538= on NM_003319.4) | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs750472100, COSV59941712; ClinVar: likely benign / benign / uncertain significance; called by muse, mutect2, varscan2
- UGT1A10 | c.414G>A p.K138= | Silent (SNP) | VAF 65/108 reads (60%) | catalogued as rs1322316630, COSV60837500; called by muse, mutect2, varscan2
- VPS13B | c.6669G>A p.G2223= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV62154866; called by muse, mutect2, varscan2
- ZMAT4 | c.180C>T p.L60= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV52712158; called by muse, mutect2, varscan2
- ZNF462 | c.6867C>T p.S2289= | Silent (SNP) | VAF 43/58 reads (74%) | catalogued as COSV52949559; called by muse, mutect2, varscan2
- ZNF638 | c.1617C>T p.S539= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV52491229; called by muse, mutect2, varscan2
- CCDC159 | c.22-539G>C | Intron (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- DNM2 | chr19:10833022 G>A | 3'Flank (SNP) | VAF 15/64 reads (23%) | catalogued as rs749744603, COSV53035220; called by muse, mutect2, varscan2
- KRT18P23 | chr22:44571445 C>T | 3'Flank (SNP) | VAF 16/35 reads (46%) | catalogued as rs764132201; called by muse, mutect2, varscan2
- MIR646 | n.73C>T | RNA (SNP) | VAF 24/50 reads (48%) | catalogued as rs941692683; called by muse, mutect2, varscan2
- NOTCH2 | c.751+260G>A | Intron (SNP) | VAF 12/43 reads (28%) | catalogued as COSV99867150; called by muse, mutect2, varscan2
- OR2W5 | n.798G>A | RNA (SNP) | VAF 32/107 reads (30%) | catalogued as rs747421516; called by muse, mutect2, varscan2
- ZNF33A | c.-76C>T | 5'UTR (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100276278; called by muse, mutect2, varscan2
